Somatic mutation profile of tumor specimen ALCH-B3A7-TTP1-A (aliquot ALCH-B3A7-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3A7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,402 days).
Specimen ALCH-B3A7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d72282-9182-4219-96ed-98921eddd9ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3A7-NB1-A (Blood Derived Normal), aliquot ALCH-B3A7-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c133ac-e3a3-4c02-86b6-e2284a7a6f9e

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 4, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 41/148 reads (28%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATG16L1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs773069973; called by muse, mutect2, varscan2
- CDK15 | c.781G>A p.V261M (on ENST00000652192 / NM_001366386.2; = p.V210M on NM_139158.2) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755877050, COSV53636913, COSV53637977; called by muse, mutect2, varscan2
- DMD | c.3046C>T p.R1016W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs199808421; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC1 | c.1157G>A p.W386* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as COSV63827525; called by muse, mutect2
- MDGA1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as rs778477613; called by muse, mutect2, varscan2
- P2RY10 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs994112446; called by muse, mutect2, varscan2
- PIK3C3 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as rs780261889; called by muse, mutect2, varscan2
- PSMA7 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as rs772364540; called by muse, varscan2
- RCBTB2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1229869065; called by muse, mutect2
- SHISA3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100069779, COSV59980086; called by muse, varscan2
- YLPM1 | c.5571G>C p.K1857N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53115492; called by muse, varscan2
- ABTB2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ALX1 | c.8T>C p.F3S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); called by muse, varscan2
- CDCA5 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EIF2A | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.439); called by muse, mutect2
- ELAPOR2 | c.937A>G p.N313D (on ENST00000450689 / NM_001142749.3; = p.N146D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EP400 | c.8128A>G p.I2710V | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.448); called by muse, varscan2
- FOXA2 | c.598C>T p.Q200* (on ENST00000377115 / NM_153675.3; = p.Q206* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2, varscan2
- FREM2 | c.6051C>G p.Y2017* | Nonsense Mutation (SNP) | VAF 73/209 reads (35%) | called by muse, mutect2, varscan2
- MYH2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.4072C>T p.Q1358* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- SEMA3A | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TRHR | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP31 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR27 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, varscan2
- ZCCHC14 | c.1861G>C p.A621P (on ENST00000268616; = p.A758P on NM_015144.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNM3 | c.744A>C p.I248= | Silent (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- DPCD | c.432T>C p.D144= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- FMNL1 | c.2400A>T p.T800= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- MMRN2 | c.1683G>A p.T561= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- MYH4 | c.5190C>T p.T1730= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1205995212, COSV55128730; called by muse, mutect2, varscan2
- DDIT4 | c.-38dup | 5'UTR (INS) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- NT5DC3 | c.1189-238C>A | Intron (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
